Somatic mutation profile of tumor specimen RC-B55B-TTP1-A (aliquot RC-B55B-TTP1-A-1-1-D-A93N-47) from RC case RC-B55B, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 69.8 years (25,500 days).
Specimen RC-B55B-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 586d657c-12e8-45db-ad04-61139e0e14c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B55B-NM1-A (Bone Marrow Components NOS; tissue type Normal), aliquot RC-B55B-NM1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7facc7b-197f-4bfc-bd38-2be92820b0b0

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 31/157 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV69041529, COSV69041693, COSV69041915, COSV69043569; called by muse, mutect2, varscan2
- CD28 | c.583A>C p.T195P | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60730968, COSV60731163; called by muse, mutect2, varscan2
- METTL11B | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.112); catalogued as COSV100883975, COSV63029864; called by muse, varscan2
- RIMS2 | c.3164G>A p.R1055H (on ENST00000666250 / NM_001348490.2; = p.R863H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs199562210, COSV51667384; called by muse, mutect2, varscan2
- SMG1 | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.935); catalogued as rs1336874576; called by muse, varscan2
- SSPOP | n.11587G>C | Splice Region (SNP) | VAF 26/92 reads (28%) | catalogued as COSV65128425; called by muse, mutect2
- TTN | c.56425G>A p.A18809T (on ENST00000591111; = p.A11385T on NM_003319.4) | Missense Mutation (SNP) | VAF 28/162 reads (17%) | PolyPhen benign (0.029); catalogued as COSV60154247; called by muse, mutect2
- ARHGAP23 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, varscan2
- FEM1C | c.528T>A p.N176K | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR7 | c.1957G>T p.D653Y | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MUC5AC | c.4580C>A p.P1527Q | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.06); called by muse, mutect2, varscan2
- SGF29 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SMG1 | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- SOX9 | c.684G>A p.S228= | Splice Region (SNP) | VAF 33/152 reads (22%) | called by muse, varscan2
- TLE1 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLE5 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TMEM60 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.56423C>A p.A18808E (on ENST00000591111; = p.A11384E on NM_003319.4) | Missense Mutation (SNP) | VAF 29/165 reads (18%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- A4GALT | c.492G>A p.G164= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as COSV50747592; called by muse, mutect2, varscan2
- FAT2 | c.10746G>A p.A3582= | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as rs745505451, COSV55828361; called by muse, mutect2, varscan2
- FGGY | c.1542G>T p.G514= | Silent (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- GRIN2A | c.2553C>T p.G851= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as rs1299544068, COSV58051235; called by muse, mutect2, varscan2
- NBPF26 | c.2490C>G p.L830= (on ENST00000620612; = p.L568= on NM_001351372.1) | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.60G>A p.V20= | Silent (SNP) | VAF 26/133 reads (20%) | called by muse, varscan2
- SMARCA2 | c.4353A>G p.K1451= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
